CCDI case PBCENA — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS.
https://portal.gdc.cancer.gov/cases/50f83230-aca6-4a86-b2b8-1722ad3d354e

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Mesenchymal chondrosarcoma: ICD-O-3 morphology code: 9240/3; Tissue or organ of origin: Thorax, NOS; Age at diagnosis: 12.6 years (4,585 days).

Biospecimens (3 samples)
- Sample 0DQ7V3: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DQ7V6: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DQ7VC: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
